Somatic mutation profile of tumor specimen TCGA-AG-4005-01A (aliquot TCGA-AG-4005-01A-01W-1073-09) from TCGA case TCGA-AG-4005, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.1 years (23,407 days).
Specimen TCGA-AG-4005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8023dde-3829-4931-bfef-cc4b1f569291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4005-10A (Blood Derived Normal), aliquot TCGA-AG-4005-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01fa76e-2b03-4f1e-8a2f-bbcd077dd86a

The open-access MAF lists 133 somatic variants for this specimen: 89 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 40, Nonsense Mutation 8, Frame Shift Del 6, Frame Shift Ins 4, Splice Region 3, Splice Site 3, RNA 2, 5'UTR 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3593C>G p.S1198* | Nonsense Mutation (SNP) | VAF 82/245 reads (33%) | catalogued as rs879254089, CM040980, CM990160, COSV57324228, COSV57371676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 113/255 reads (44%) | hotspot (GDC flag); catalogued as rs398123121, CM930028, COSV57324976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 50/77 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 99/143 reads (69%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPT1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771962601, COSV52432532, COSV99033911; called by muse, mutect2
- APBA1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs769199164, COSV55222649; called by muse, mutect2, varscan2
- APOB | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780537483, COSV51925657, COSV51942565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXDND1 | c.1016T>A p.L339Q | Missense Mutation (SNP) | VAF 151/583 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV62640252; called by muse, mutect2, varscan2
- AXIN2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61055994; called by muse, mutect2, varscan2
- C4A | c.2695T>C p.F899L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71177475; called by mutect2, varscan2
- CABIN1 | c.4078G>A p.V1360I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs568317451, COSV54078543; called by muse, mutect2, varscan2
- CACHD1 | c.1007-1G>C p.X336_splice | Splice Site (SNP) | VAF 50/160 reads (31%) | catalogued as COSV51555381; called by muse, mutect2, varscan2
- CACNB4 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1033751911, COSV52389903; called by muse, mutect2, varscan2
- CADM2 | c.196T>G p.F66V (on ENST00000407528 / NM_001167674.2; = p.F68V on NM_153184.4) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67409327; called by muse, mutect2
- CCPG1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310927982, COSV60524263; called by muse, mutect2
- CHST9 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779405504, COSV52431099; called by muse, mutect2
- CLEC1A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1385478606, COSV59531103; called by muse, mutect2, varscan2
- CSMD2 | c.3804C>T p.V1268= | Splice Region (SNP) | VAF 113/221 reads (51%) | catalogued as rs543673574, COSV53885585; called by muse, mutect2, varscan2
- CTNNA2 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs559758762, COSV63550267; called by muse, mutect2, varscan2
- CYP11A1 | c.483_486del p.E162Pfs*63 | Frame Shift Del (DEL) | VAF 51/82 reads (62%) | catalogued as COSV51430851; called by mutect2, pindel, varscan2
- DAB1 | c.210C>T p.G70= | Splice Region (SNP) | VAF 51/105 reads (49%) | catalogued as rs143307821; called by muse, mutect2, varscan2
- DLG2 | c.605-1G>C p.X202_splice | Splice Site (SNP) | VAF 66/232 reads (28%) | catalogued as COSV99717259; called by muse, mutect2, varscan2
- DNAH11 | c.5908A>G p.R1970G | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60943032; called by muse, mutect2, varscan2
- ESRRA | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1258452217, COSV50004817; called by muse, mutect2, varscan2
- FAM184A | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 82/121 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.087); catalogued as COSV58852083; called by muse, mutect2, varscan2
- FAM47C | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 171/212 reads (81%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.748); catalogued as rs782140924, COSV63724165; called by muse, mutect2, varscan2
- FLG2 | c.5590C>A p.Q1864K | Missense Mutation (SNP) | VAF 143/674 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.346); catalogued as COSV66167007; called by muse, mutect2, varscan2
- FN1 | c.4796T>C p.I1599T | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60547786; called by muse, mutect2, varscan2
- FNDC3B | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61038322; called by muse, mutect2, varscan2
- GAP43 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 107/310 reads (35%) | catalogued as COSV59342826; called by muse, mutect2, varscan2
- GNGT1 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV50352403; called by muse, mutect2, varscan2
- GPC3 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 259/299 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63659876; called by muse, mutect2, varscan2
- H2BC3 | c.120_123del p.I40Mfs*6 | Frame Shift Del (DEL) | VAF 47/385 reads (12%) | catalogued as rs757602618; called by pindel, varscan2
- IGKV1D-16 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 125/484 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs375652808; called by muse, mutect2, varscan2
- ITGA4 | c.2081A>G p.K694R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.929); catalogued as COSV67896399; called by muse, mutect2, varscan2
- LRP1B | c.3935T>G p.I1312R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101253037, COSV67192454; called by muse, mutect2, varscan2
- MAP1B | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 92/426 reads (22%) | catalogued as COSV57094771; called by muse, mutect2, varscan2
- MAPK10 | c.404T>C p.M135T (on ENST00000359221 / NM_001351625.2; = p.M173T on NM_002753.5) | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1203901775, COSV60377008; called by muse, mutect2, varscan2
- METTL21C | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 231/384 reads (60%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs767043904, COSV57432245; called by muse, mutect2, varscan2
- MPRIP | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs745846220, COSV57925761; called by muse, mutect2
- NCF2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62314876; called by muse, varscan2
- NCKAP5 | c.4673C>G p.P1558R | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as rs771327327, COSV58430492; called by muse, mutect2, varscan2
- NHS | c.1604A>G p.D535G | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV66272086; called by muse, mutect2, varscan2
- NLRP5 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs759300867, COSV66762557; called by muse, mutect2, varscan2
- NTSR2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60990604; called by muse, mutect2, varscan2
- NUP85 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs760257294, COSV55463088; called by muse, mutect2, varscan2
- OPCML | c.1037G>C p.*346Sext*1 | Nonstop Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV59408045; called by muse, mutect2, varscan2
- OR10J3 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 151/591 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59953755; called by muse, mutect2, varscan2
- OR52B4 | c.922T>G p.F308V | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68768627, COSV68769204; called by muse, mutect2, varscan2
- OR5B21 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 161/583 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64481639; called by muse, mutect2, varscan2
- OTC | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50000472; called by muse, mutect2, varscan2
- PADI6 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753997866, COSV61883855; called by muse, mutect2, varscan2
- PAQR9 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV61417685; called by muse, mutect2, varscan2
- PDIA4 | c.1850A>T p.K617I (on ENST00000286091 / NM_001371244.1; = p.K616I on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV53723584; called by muse, mutect2, varscan2
- PDPN | c.448G>A p.V150I (on ENST00000621990; = p.V226I on NM_006474.4) | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377220172; called by muse, mutect2, varscan2
- PLG | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as CM991052, COSV51981163, COSV51985870; called by muse, mutect2, varscan2
- PRKD1 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 96/132 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as COSV59560717, COSV59570344; called by muse, mutect2, varscan2
- PTPRU | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60522980; called by muse, mutect2, varscan2
- RBM26 | c.2626C>T p.R876* (on ENST00000438737 / NM_001366735.2; = p.R849* on NM_022118.5) | Nonsense Mutation (SNP) | VAF 159/294 reads (54%) | catalogued as COSV57391955; called by muse, mutect2, varscan2
- SACS | c.7333G>T p.E2445* | Nonsense Mutation (SNP) | VAF 35/327 reads (11%) | catalogued as COSV66535573; called by muse, mutect2, varscan2
- SDK1 | c.5859C>A p.D1953E | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as COSV67358575; called by muse, mutect2, varscan2
- SGTA | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55593365; called by muse, mutect2, varscan2
- SLC30A3 | c.613dup p.H205Pfs*6 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as rs745429257; called by mutect2, varscan2
- SPOCK3 | c.726T>A p.D242E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV62718375, COSV62732074; called by muse, mutect2, varscan2
- SPOCK3 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV62718382; called by muse, mutect2, varscan2
- STAT4 | c.1254C>A p.G418= | Splice Region (SNP) | VAF 29/186 reads (16%) | catalogued as COSV61828273; called by muse, mutect2, varscan2
- TCOF1 | c.4033C>T p.R1345C (on ENST00000377797 / NM_001135243.1; = p.R1268C on NM_000356.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs781234452, COSV60346436; called by muse, mutect2
- TEFM | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs779707509, COSV60091508; called by muse, mutect2, varscan2
- TPTE2 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 59/77 reads (77%) | catalogued as COSV55017005, COSV55017692; called by muse, mutect2, varscan2
- TRIM67 | c.2021G>T p.S674I | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1057250113, COSV64158262; called by muse, mutect2, varscan2
- UBASH3B | c.1576A>T p.S526C | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV52491142; called by muse, mutect2, varscan2
- ULK4 | c.2473T>A p.L825M | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57200760; called by muse, mutect2, varscan2
- WASF3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 263/734 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs770264821, COSV58963122; called by muse, mutect2, varscan2
- WDR64 | c.3189_3190insC p.N1064Qfs*69 | Frame Shift Ins (INS) | VAF 21/137 reads (15%) | catalogued as COSV63793133; called by mutect2, pindel, varscan2
- ZMYM1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV63250610; called by muse, mutect2, varscan2
- ZNF687 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60682033; called by muse, mutect2
- ANKRD20A4P | c.1137A>C p.E379D | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- BCL9L | c.2819_2820del p.V940Afs*72 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- ERVW-1 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.467); called by muse, mutect2
- FAM114A2 | c.1219del p.E407Kfs*2 | Frame Shift Del (DEL) | VAF 87/432 reads (20%) | called by mutect2, pindel, varscan2
- HCN1 | c.849+2T>A p.X283_splice | Splice Site (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- KCNAB1 | c.224_228dup p.L77Afs*36 | Frame Shift Ins (INS) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- MTM1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- MUC15 | c.505A>T p.S169C | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- MYH7B | c.3063_3064del p.N1021Kfs*36 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- SLITRK4 | c.2034del p.D679Mfs*3 | Frame Shift Del (DEL) | VAF 60/152 reads (39%) | called by mutect2, pindel, varscan2
- TIAM2 | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADORA1 | c.657C>T p.S219= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as rs201016113, COSV55141536; called by muse, mutect2, varscan2
- AGBL5 | c.2385G>A p.P795= | Silent (SNP) | VAF 93/321 reads (29%) | catalogued as rs780640995, COSV64079234; called by muse, mutect2, varscan2
- APOB | c.11922G>A p.A3974= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as rs927432508, COSV51925645; called by muse, mutect2, varscan2
- ARHGEF26 | c.630T>A p.S210= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV62844276; called by muse, mutect2, varscan2
- BRINP3 | c.1554C>T p.D518= | Silent (SNP) | VAF 109/232 reads (47%) | catalogued as COSV66514997; called by muse, mutect2, varscan2
- CALM2 | c.18T>C p.T6= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs1370741943, COSV55398882; called by muse, mutect2, varscan2
- CCDC62 | c.813G>A p.A271= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as rs756265250, COSV53430813; called by muse, mutect2
- CD300C | c.414A>G p.T138= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1327612342, COSV58169737; called by muse, mutect2, varscan2
- CNTNAP5 | c.2247C>A p.G749= | Silent (SNP) | VAF 57/107 reads (53%) | catalogued as rs1190827536, COSV70475438; called by muse, mutect2, varscan2
- CYFIP2 | c.2844G>A p.Q948= (on ENST00000616178 / NM_001291722.2; = p.Q923= on NM_014376.4) | Silent (SNP) | VAF 121/241 reads (50%) | catalogued as COSV59029770; called by muse, mutect2, varscan2
- DCBLD2 | c.2151A>T p.T717= | Silent (SNP) | VAF 116/564 reads (21%) | catalogued as COSV54579412; called by muse, mutect2, varscan2
- DIP2B | c.4008T>G p.T1336= | Silent (SNP) | VAF 132/267 reads (49%) | catalogued as COSV56579723, COSV56590288; called by muse, mutect2, varscan2
- FARP1 | c.1575G>A p.T525= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs761873715, COSV60331292; called by muse, mutect2, varscan2
- FBXL2 | c.900C>T p.T300= | Silent (SNP) | VAF 94/257 reads (37%) | catalogued as rs377078642; called by muse, mutect2, varscan2
- FNIP1 | c.3105G>C p.V1035= | Silent (SNP) | VAF 68/341 reads (20%) | called by muse, mutect2, varscan2
- GET4 | c.672G>A p.P224= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs368468235; called by muse, mutect2, varscan2
- HS6ST3 | c.1059C>T p.L353= | Silent (SNP) | VAF 192/780 reads (25%) | catalogued as COSV65003359; called by muse, mutect2, varscan2
- HSPA4L | c.816A>G p.K272= | Silent (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- ICE2 | c.519C>G p.L173= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as rs1442658568, COSV55030103; called by muse, mutect2, varscan2
- IRS1 | c.669C>T p.I223= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV59333391; called by muse, mutect2, varscan2
- MCF2L | c.2295G>T p.L765= (on ENST00000375608; = p.L733= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV56176024; called by muse, mutect2
- MNDA | c.372G>A p.S124= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs144118208; called by muse, mutect2, varscan2
- MYSM1 | c.246G>A p.P82= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs748786067, COSV68977071; called by muse, mutect2, varscan2
- NCAM2 | c.2235C>T p.G745= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs757142384, COSV53059617; called by muse, mutect2, varscan2
- NEB | c.7845C>T p.C2615= | Silent (SNP) | VAF 96/410 reads (23%) | catalogued as COSV50831278; called by muse, mutect2
- ODF3L1 | c.753C>T p.H251= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- OR5A1 | c.195C>T p.F65= | Silent (SNP) | VAF 105/512 reads (21%) | catalogued as COSV57375981; called by muse, mutect2, varscan2
- OR5A1 | c.639G>A p.S213= | Silent (SNP) | VAF 220/338 reads (65%) | catalogued as rs770324514, COSV57375747; called by muse, mutect2, varscan2
- PCDHA2 | c.1527G>A p.S509= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV65370386; called by muse, mutect2, varscan2
- PCDHGB1 | c.102G>A p.T34= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV53908831; called by muse, mutect2, varscan2
- PDGFC | c.357A>T p.I119= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- PTX4 | c.306G>A p.A102= (on ENST00000447419 / NM_001328608.2; = p.A97= on NM_001013658.1) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs753975522, COSV53514575; called by muse, mutect2, varscan2
- SH3PXD2A | c.177C>T p.P59= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV63508085; called by muse, mutect2, varscan2
- ST8SIA5 | c.852C>T p.N284= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs770653498, COSV59330321; called by muse, mutect2, varscan2
- TBC1D3F | c.294G>A p.A98= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs1257218331; called by muse, mutect2, varscan2
- TBX19 | c.414T>A p.A138= | Silent (SNP) | VAF 45/173 reads (26%) | catalogued as COSV63196875; called by muse, mutect2, varscan2
- TDRD9 | c.3939G>A p.A1313= | Silent (SNP) | VAF 90/127 reads (71%) | catalogued as rs781346716, COSV59143268; called by muse, mutect2, varscan2
- TSC1 | c.2901C>T p.G967= | Silent (SNP) | VAF 54/233 reads (23%) | catalogued as rs774634388, COSV53764358; ClinVar: benign; called by muse, mutect2, varscan2
- TSKS | c.1041G>A p.A347= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs923211595, COSV55873299; called by muse, mutect2, varscan2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as rs147863190; called by muse, mutect2, varscan2
- GABRG1 | c.-2C>T | 5'UTR (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- GRK5 | c.148+7167G>A | Intron (SNP) | VAF 22/112 reads (20%) | catalogued as rs781405182, COSV101230347; called by muse, mutect2, varscan2
- HLA-L | n.697G>T | RNA (SNP) | VAF 37/183 reads (20%) | called by muse, mutect2, varscan2
- MIR31 | n.30T>G | RNA (SNP) | VAF 58/277 reads (21%) | called by muse, mutect2, varscan2
